Somatic mutation profile of tumor specimen 0DTM9W from CCDI case PBCJXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,287 days).
Specimen 0DTM9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b9ce990-7a7d-485d-b9af-aa1a4cbbf7d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTMA1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a0d10a1-07ca-4f6a-84c2-5405755eaf56

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC8A1 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 31/1009 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1191275018, COSV100245325; called by muse, mutect2
- ZSCAN10 | c.2002C>G p.P668A (on ENST00000252463; = p.P723A on NM_032805.3) | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs758225857; called by muse, mutect2, varscan2
- ABCC9 | c.4130T>C p.I1377T | Missense Mutation (SNP) | VAF 118/1559 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- USP5 | c.1037G>C p.S346T | Missense Mutation (SNP) | VAF 234/604 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CDPF1 | c.108G>A p.S36= | Silent (SNP) | VAF 263/789 reads (33%) | catalogued as rs200548847; called by muse, mutect2, varscan2
- SBSN | c.921C>T p.A307= | Silent (SNP) | VAF 70/522 reads (13%) | catalogued as rs749650252; called by muse, mutect2, varscan2
- TMEM266 | c.1266C>T p.P422= | Silent (SNP) | VAF 248/702 reads (35%) | catalogued as rs775662721; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 46/426 reads (11%) | called by muse, varscan2
